Somatic mutation profile of tumor specimen 0DVJOJ from CCDI case PBCMNZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.3 years (3,038 days).
Specimen 0DVJOJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f98dbba-6396-4b14-bd13-953a96bf4afe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/faeb614d-a8f4-411d-85d3-87b81e75dcd4

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Splice Site 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP39 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as rs150289481; called by muse, varscan2
- GABRG1 | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 101/398 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.352); catalogued as COSV54953479; called by muse, varscan2
- KDM6A | c.3764G>T p.R1255L | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65038941; called by muse, varscan2
- KMT2C | c.4541-1G>T p.X1514_splice | Splice Site (SNP) | VAF 56/254 reads (22%) | catalogued as COSV100070545, COSV51405075; called by muse, varscan2
- RBBP6 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs749512462; called by muse, varscan2
- ZFPM2 | c.2761A>C p.N921H | Missense Mutation (SNP) | VAF 98/368 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.34); catalogued as rs757308103, COSV65873865; called by muse, varscan2
- ZNF20 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 115/305 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs746132891; called by muse, varscan2
- ZNF248 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRIM3 | c.867G>A p.R289= | Silent (SNP) | VAF 85/133 reads (64%) | called by muse, varscan2
- NOL8 | c.-48-42A>G | Intron (SNP) | VAF 12/57 reads (21%) | called by muse, varscan2
